Somatic mutation profile of tumor specimen TCGA-DS-A5RQ-01A (aliquot TCGA-DS-A5RQ-01A-11D-A28B-09) from TCGA case TCGA-DS-A5RQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 80.8 years (29,526 days).
Specimen TCGA-DS-A5RQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e67e40e-e1df-4dff-89d3-da5942e2df96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A5RQ-10A (Blood Derived Normal), aliquot TCGA-DS-A5RQ-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54ea69ed-564b-4b55-92ec-5cbfb8d0616d

The open-access MAF lists 115 somatic variants for this specimen: 76 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 35, Nonsense Mutation 8, Intron 1, Splice Site 1, 3'UTR 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDS | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193302904, CM149683; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TGFBR2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039551, CM060085, CM086981, COSV55445539, COSV55457221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as COSV61658930; called by muse, mutect2, varscan2
- ADAM8 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs375767499; called by muse, mutect2, varscan2
- ADCY9 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.148); catalogued as rs759674069, COSV53578661; called by muse, mutect2, varscan2
- ADGRL3 | c.1189G>A p.D397N (on ENST00000506720 / NM_001322402.2; = p.D329N on NM_015236.6) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780445734, COSV72273949; called by muse, mutect2, varscan2
- APCS | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99661194; called by muse, mutect2, varscan2
- BICD2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs765563734; called by muse, mutect2, varscan2
- CA11 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99320926; called by muse, mutect2, varscan2
- CACNA1C | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs533892755, COSV59698705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC63 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs774363534; called by muse, mutect2, varscan2
- CMSS1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs752532070; called by muse, mutect2, varscan2
- CPNE7 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs369886930; called by muse, mutect2, varscan2
- CYP19A1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV53062773; called by muse, mutect2, varscan2
- DYNLRB1 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1436293308; called by muse, mutect2, varscan2
- EZHIP | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.319); catalogued as COSV57955886; called by muse, mutect2, varscan2
- GCN1 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1039785524; called by muse, mutect2, varscan2
- GPR142 | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59519076; called by muse, mutect2, varscan2
- GPR149 | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101078444; called by muse, mutect2, varscan2
- GRK2 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV57752358; called by muse, mutect2
- HLCS | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs149399432, CM013743, CM032941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPDH1 | c.479G>A p.R160Q (on ENST00000470772 / NM_001142573.2; = p.R246Q on NM_000883.4) | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as rs201071873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JARID2 | c.1999G>A p.G667S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272384842; called by muse, mutect2, varscan2
- MAGEB1 | c.729G>C p.K243N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV104430151; called by muse, mutect2, varscan2
- MAGEC3 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV68924432; called by muse, mutect2, varscan2
- MAP4 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1175301036; called by muse, mutect2, varscan2
- MAPK6 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV55929974; called by muse, mutect2, varscan2
- MROH2B | c.48C>A p.N16K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.724); catalogued as rs562749956; called by muse, varscan2
- PPP1R9A | c.2423T>C p.V808A | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99198410; called by muse, mutect2, varscan2
- PTPRB | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.217); catalogued as rs1239383943, COSV99718190; called by muse, mutect2, varscan2
- PZP | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs762420379, COSV54361607; called by muse, mutect2
- SAP130 | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as rs781471032, COSV52099641; called by muse, mutect2, varscan2
- SLC25A18 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs769347497, COSV100541205; called by muse, mutect2, varscan2
- TGFBI | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777393341; called by muse, mutect2, varscan2
- TSPEAR | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs782159618, COSV100555399; called by muse, mutect2, varscan2
- TTN | c.54926G>A p.R18309Q (on ENST00000591111; = p.R10885Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | PolyPhen probably damaging (0.947); catalogued as rs374914334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBA1 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as COSV100255627, COSV60111795; called by muse, mutect2, varscan2
- UBR5 | c.1608G>C p.L536F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV55284726, COSV99642285; called by muse, mutect2, varscan2
- WDR90 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as rs946115496, COSV99553915; called by muse, mutect2, varscan2
- WLS | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs764113746, COSV52042270; called by muse, mutect2, varscan2
- ZNF804A | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.212); catalogued as COSV100167933, COSV100168596; called by muse, mutect2
- ARHGAP31 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- AUNIP | c.207_220+1del p.X69_splice | Splice Site (DEL) | VAF 14/22 reads (64%) | called by mutect2, pindel, varscan2
- BCOR | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- BEND3 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BORA | c.1453C>T p.Q485* (on ENST00000613797; = p.Q410* on NM_024808.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- CACNB1 | c.36C>A p.Y12* | Nonsense Mutation (SNP) | VAF 33/41 reads (80%) | called by muse, mutect2, varscan2
- CCDC180 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CDK13 | c.3490C>T p.Q1164* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- CEP162 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- CUL7 | c.3579C>A p.F1193L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB12 | c.458G>A p.R153K (on ENST00000338820; = p.R119K on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- DRAM1 | c.109_120del p.N37_L40del | In Frame Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- EIF5B | c.3097G>A p.V1033I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- FLACC1 | c.268G>C p.V90L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2
- FOXM1 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HTATSF1 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- INF2 | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDM3A | c.3774C>G p.I1258M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MED12L | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NHS | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4C15 | c.947C>T p.S316F (on ENST00000314644; = p.S262F on NM_001001920.2) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- P2RX6 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- PBX3 | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB3 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCYT1A | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SASH3 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD5 | c.3398C>T p.S1133F | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- SFTPD | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC6 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPP2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- UBE2Z | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- YPEL1 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF711 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADAMTS16 | c.2325C>T p.R775= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- ADGRE5 | c.1317C>T p.L439= (on ENST00000242786 / NM_078481.4; = p.L346= on NM_001784.5) | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV54410583; called by muse, mutect2, varscan2
- ADH4 | c.855G>A p.L285= | Silent (SNP) | VAF 11/35 reads (31%) | called by mutect2, varscan2
- ANKRD24 | c.3198C>T p.F1066= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- AP1B1 | c.1227G>A p.E409= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100434764; called by muse, mutect2, varscan2
- ATXN3L | c.777C>T p.S259= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV66075266; called by muse, mutect2, varscan2
- BANP | c.1524G>A p.E508= (on ENST00000286122; = p.E458= on NM_017869.4) | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- CACNA1H | c.4974C>T p.I1658= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100673368; called by muse, mutect2, varscan2
- CAMTA1 | c.1092C>T p.S364= | Silent (SNP) | VAF 33/44 reads (75%) | catalogued as rs370847468; called by muse, mutect2, varscan2
- CFAP100 | c.1299C>T p.V433= | Silent (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- CLASP1 | c.3408G>A p.A1136= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs759088930, COSV55325659; called by mutect2, varscan2
- COL12A1 | c.939C>T p.I313= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1049592759; called by muse, mutect2, varscan2
- DIDO1 | c.6687G>A p.S2229= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs372132324; called by muse, mutect2, varscan2
- ETV4 | c.432T>C p.G144= | Silent (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- FSCN1 | c.933G>A p.T311= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- GBX2 | c.123C>T p.Y41= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, varscan2
- GRIN1 | c.1149C>T p.G383= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs138398771; ClinVar: benign; called by muse, mutect2, varscan2
- IRX1 | c.282G>A p.S94= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs769262251, COSV57361661, COSV57362428; called by muse, mutect2, varscan2
- MS4A15 | c.561G>A p.A187= (on ENST00000405633 / NM_001098835.2; = p.A94= on NM_152717.3) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs771549901, COSV61962005; called by muse, mutect2, varscan2
- MUC5B | c.16824C>T p.S5608= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- MXRA5 | c.5568C>T p.L1856= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- NOL10 | c.1497G>A p.E499= | Silent (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- NUDT18 | c.228G>A p.G76= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV99248838, COSV99249083; called by muse, mutect2, varscan2
- NUP188 | c.2571A>G p.K857= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs758825786; called by muse, mutect2, varscan2
- PAM | c.1617G>A p.S539= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs760101423, COSV57219068; called by muse, mutect2, varscan2
- PCDH15 | c.3936A>G p.A1312= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs398124433; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PDZRN4 | c.2589C>T p.V863= (on ENST00000402685 / NM_001164595.2; = p.V605= on NM_013377.4) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV54198482, COSV54200283; called by muse, mutect2, varscan2
- PIGO | c.1020C>T p.I340= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs777808521; ClinVar: likely benign; called by muse, mutect2, varscan2
- PXDN | c.1215G>C p.G405= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99414699; called by muse, varscan2
- SIGLEC12 | c.1077C>T p.L359= (on ENST00000291707 / NM_053003.4; = p.L241= on NM_033329.2) | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs781026072; called by muse, varscan2
- SIGLEC12 | c.981C>G p.L327= (on ENST00000291707 / NM_053003.4; = p.L209= on NM_033329.2) | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, varscan2
- SLC29A3 | c.741C>G p.L247= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV64384381; called by muse, mutect2, varscan2
- SND1 | c.2253G>A p.E751= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- TRAPPC10 | c.1686G>A p.E562= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- ZAN | c.909C>T p.L303= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs1342743126; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852137 G>A | 3'Flank (SNP) | VAF 6/38 reads (16%) | catalogued as rs935672183; called by muse, mutect2, varscan2
- SNORD115-36 | n.9G>A | RNA (SNP) | VAF 20/76 reads (26%) | called by muse, varscan2
- WNT4 | c.313+2330C>T | Intron (SNP) | VAF 49/78 reads (63%) | called by muse, mutect2, varscan2
- XIRP2 | c.*960C>A | 3'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs746206744, COSV99747626; called by muse, varscan2
